Gene-level copy-number profile of tumor specimen TCGA-CR-7372-01A from TCGA case TCGA-CR-7372, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 45.5 years (16,610 days).
Specimen TCGA-CR-7372-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.d9c83d5b-c957-44ed-ac2b-bd650d2de308.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-7372-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/43427ffe-6dd4-45b3-aa1f-ae768353c907

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 776; copy number 2: 18,114; copy number 3: 20,261; copy number 4: 7,433; copy number 5: 12,604; copy number 6: 208; copy number 7: 69; copy number 8: 181; copy number 10: 58; copy number 13: 37; copy number 19: 52; copy number 29: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-7372-01A-11D-2010-01): tumor purity 0.41, ploidy 2.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 412 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:119,993,199–121,088,726, 23 genes, copy number 7: RPL27P7, EPB41L5, AC012363.1, Y_RNA, MTATP6P26, MTCO3P43, MTND3P10, MTND4LP14, MTND4P26, MTND5P28, TMEM185B, RALB, AC012363.2, INHBB, LINC01101, AC073257.2, AC073257.1, Y_RNA, AC018866.1, GLI2, AC017033.1, Y_RNA, AC067960.1.
- chr8:46,549,089–49,229,174, 63 genes, copy number 13–29 (broad region; genes not listed).
- chr9:32,886,601–34,134,696, 58 genes, copy number 10 (within-gene range 5–10): APTX, BOLA3P4, ASS1P12, TCEA1P4, LAGE3P1, DNAJA1, SMU1, B4GALT1, B4GALT1-AS1, RNU4ATAC15P, SPINK4, BAG1, CHMP5, NFX1, Y_RNA, AQP7, AL356218.2, AQP3, AL356218.1, NOL6, MIR6851, SUGT1P1, AL139008.2, ANKRD18B, AL139008.1, SNX18P7, CYP4F26P, PRSS3P4, TRBV20OR9-2, ANXA2P2, TRBV21OR9-2, TRBV22OR9-2, TRBV23OR9-2, TRBV24OR9-2, TRBV25OR9-2, PTENP1, PTENP1-AS, TRBV26OR9-2, AL356489.2, AL356489.3, AL356489.1, AL356489.4, LINC01251, PRSS3, UBE2R2-AS1, TRBV29OR9-2, UBE2R2, Y_RNA, RNU4ATAC11P, UBAP2, SNORD121B, SNORD121A, OSTCP8, RN7SKP114, AL354989.1, DCAF12, TUBB4BP2, AL354989.2.
- chr9:35,147,410–37,503,697, 87 genes, copy number 7–19 (within-gene range 2–19) (broad region; genes not listed).
- chr12:106,015,897–111,685,956, 139 genes, copy number 8 (broad region; genes not listed).
- chr22:31,488,688–31,618,588, 1 gene, copy number 8 (within-gene range 5–8): SFI1.
- chr22:31,538,352–32,386,868, 41 genes, copy number 8: AL096701.2, AL096701.1, PISD, MIR7109, PRR14L, DEPDC5, Z82190.2, RN7SL20P, AL022331.1, RNU6-201P, Z82190.1, C22orf24, YWHAH, AL008719.1, LINC02558, RN7SL305P, Z74021.1, SLC5A1, AP1B1P1, Z83839.1, AP1B1P2, Z83839.2, C22orf42, AL008723.1, AL008723.3, RFPL2, IGLCOR22-1, SLC5A4-AS1, SLC5A4, CPSF1P1, AL008723.2, AL021937.3, RFPL3, IGLCOR22-2, RFPL3S, AL021937.6, AL021937.5, AL021937.1, IGLVIVOR22-2, AL021937.4, AL021937.2.

Autosomal genes at a single copy (total copy number 1): 662. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
